Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3AY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3AY-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]
Copy To:

Service: [REDACTED]
Visit #: [REDACTED]
Location: [REDACTED]
Facility:

Accession #: [REDACTED]
Collected: [REDACTED]
Received: [REDACTED]
Reported:

Specimen(s) Received

1. Omentum: omentum
2. Uterus: Uterus, cervix, bilateral tubes & ovaries
3. Lymph node: Rt. pelvic nodes
4. Lymph node: Lt. pelvic nodes

Diagnosis

1. Omentum:

Negative for carcinoma

2. Uterus, cervix, bilateral ovaries and fallopian tubes:

Uterus:

Endometrial adenocarcinoma, endometrioid type, FIGO grade 3/3 with:

- Invasion up to 50% of myometrium
- Involvement of lower uterine segment
- Positive for glandular involvement of cervix
- Negative for stromal involvement of cervix
- Positive for lymphovascular space invasion

Right and left ovaries: negative for tumor

Right and left fallopian tubes: negative for tumor

3. Lymph nodes, right pelvic:

Twelve lymph nodes negative for carcinoma (0/12)

4. Lymph nodes, left pelvic:

Thirteen lymph nodes negative for carcinoma (0/13)

Synoptic Data

Specimen:	Uterine corpus
	Cervix
	Right ovary
	Left ovary
	Right fallopian tube
	Left fallopian tube
	Omentum

Page 1 of 3

ICD-0-3

adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1 in 11/13/11

[page 2 of 3]
Surgical Pathology Consultation Report

Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy Omentectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Size:	Greatest dimension: 5 cm
Histologic Type:	Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade:	FIGO grade 3
Myometrial Invasion:	Present Myometrial thickness: 20 mm 50% or greater myometrial invasion
Involvement of Cervix:	Not involved
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved
Lymph-Vascular Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1b (IB): Tumor invades more than one-half of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Pelvic lymph nodes examined: 22 Pelvic lymph nodes involved: 0 Para-aortic lymph nodes examined: 0 Para-aortic lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Electronically verified by:

Clinical History

endometrial ca

Gross Description

1. The specimen container is labeled with the patient's name and as "omentum" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 10.5 x 7.0 x 1.0 cm and weighs 21.3 g. On serial sectioning, the cut surface is predominantly fatty with no nodules identified grossly. Representative sections are submitted as follows:

1A-1E- representative sections submitted.

2. The specimen container is labeled with the patient's name and as "Uterus, cervix, bilateral tubes and ovaries" contains a uterus, cervix, bilateral fimbriated fallopian tube and bilateral ovaries received in 10% buffered formalin. The uterus measures 9.2 cm SI x 5.2 cm ML x 4.0 cm AP and the cervix measures 2.9 cm. in diameter with a 1.0 cm oval shaped os. The right and left fimbriated fallopian tube measures 4.0 cm in length and 0.5 cm in diameter and 5.0 cm in length and 0.4 cm in diameter respectively. The right and left ovary measures 1.8 x 1.1 x 0.5 cm and 1.6 x 1.3 x 0.5 cm respectively. The entire specimen weighs 166.3 g. The cut surface of the right and left ovary is solid in consistency and yellow-tan to gray-tan in color. Both fallopian tubes are fimbriated and congested. The ectocervical and endocervical mucosa are grossly unremarkable. There is a friable, polypoid endometrial tumor mass occupying the anterior and posterior endometrium extending from upper to lower uterine segment approaching the endocervix measuring 5.0 cm SI x 4.5 cm ML and with a depth of 1.2 cm into the myometrium. The tumor is gray-tan in color, solid in consistency and friable. The myometrium is slightly thickened and contains multiple well-circumscribed nodules/ fibroid measuring up to 0.8 cm. The uterine serosa is congested with hemorrhagic fibrous adhesions. Representative sections are submitted as follows:

2A-2B- right ovary submitted in toto.
2C-2D- right fallopian tube and right fimbria submitted in toto.

[page 3 of 3]
Surgical Pathology Consultation Report

2E-left ovary submitted in toto.

2F-2G-left fallopian tube and left fimbria submitted in toto.

2H-2J-full transverse sections of the anterior endomyometrium with tumor

2K-2M-longitudinal section of the anterior endomyometrium from upper to lower including the cervix.

2N-2P-full transverse sections of the posterior endomyometrium with tumor

2Q-2S-longitudinal section of the posterior endomyometrium from upper to lower including the cervix.

ADDITIONAL BLOCKS:

2T-2U- anterior cervix

2V-2W- posterior cervix.

One piece of left fallopian tube, left ovary, right fallopian tube, right ovary and one piece endometrial cancer are stored frozen.

3. The specimen container labelled with the patient's name and as "Lymph Node: Right pelvic nodes" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 5.0 x 3.8 x 2.5 cms. . Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 1.0 cm to 1.7 cm. The specimen is submitted in toto as follows:

3A- one lymph node bisected.

3B- one lymph node bisected

3C-one lymph node bisected

3D- one lymph node bisected

3E-multiple lymph nodes.

3F-3J-remainder of fatty tissue.

4. The specimen container labelled with the patient's name and as "Lymph Node: Left pelvic nodes" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 4.5 x 3.0 x 2.0 cms. . Within the fatty tissue, multiple lymph nodes are identified grossly ranging in size from 0.5 cm to 1.4 cm. The specimen is submitted in toto as follows:

4A- multiple lymph nodes

4B- multiple lymph nodes

4C-4H-remainder of fatty tissue.

Source: NCI Genomic Data Commons file 786efc2f-2e8d-48a0-936f-db820c099c2f (TCGA-EO-A3AY.330AEFE0-D564-4799-8928-B05280BACA91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).